Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8EH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8EH-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

"Biopsy of the cervix":

Moderately differentiated invasive squamous cell carcinoma.

ICD-O-3

Carcinoma, squamous cell
NOS 8070/3

Site: Cervix NOS C53.9

10/21/13

Diagnostic Discrepancy		✓

Source: NCI Genomic Data Commons file f06eea64-3a1a-4a90-9338-ba4048fcfd85 (TCGA-VS-A8EH.0CC29204-715D-465B-8F93-7DE27B85FD5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).